Somatic mutation profile of cancer-model specimen HCM-CSHL-0237-C18-85A (3D Organoid; aliquot HCM-CSHL-0237-C18-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0237-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.3 years (26,416 days).
Specimen HCM-CSHL-0237-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bee22ceb-4c33-458c-89a5-360eb8a34a65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0237-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0237-C18-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1df2a21b-93f5-4834-81f8-f433427351d6

The open-access MAF lists 145 somatic variants for this specimen: 102 protein-altering or splice-affecting, 31 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 31, Intron 7, Nonsense Mutation 5, Splice Site 4, 3'UTR 3, Splice Region 2, 5'UTR 2, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 62/62 reads (100%) | catalogued as rs1554074738, CM106349, COSV57324862, COSV99966134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 366/368 reads (99%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AAMP | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1311657014, COSV99816538; called by muse, mutect2, varscan2
- APOBEC3C | c.17+2T>C p.X6_splice | Splice Site (SNP) | VAF 77/187 reads (41%) | catalogued as COSV63865125; called by muse, mutect2, varscan2
- ARSG | c.548A>G p.Q183R | Missense Mutation (SNP) | VAF 109/246 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746614421; called by muse, mutect2, varscan2
- BCL11B | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV61735288; called by muse, mutect2, varscan2
- BRIP1 | c.2090C>T p.S697F | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51994743; called by muse, mutect2, varscan2
- C16orf70 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as rs776164057, COSV54625726; called by muse, mutect2, varscan2
- C2orf78 | c.2456C>A p.S819Y | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV101280958; called by muse, mutect2, varscan2
- CD5 | c.57C>T p.V19= | Splice Region (SNP) | VAF 36/85 reads (42%) | catalogued as rs923646552; called by muse, mutect2, varscan2
- CD5 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 56/307 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1276111056, COSV61718230, COSV61718695; called by muse, mutect2, varscan2
- CFAP20DC | c.2299C>T p.R767C (on ENST00000482387 / NM_001351530.2; = p.R516C on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 164/351 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs772778129, COSV55918830; called by muse, mutect2, varscan2
- CFAP46 | c.3100G>A p.A1034T | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs777460078; called by muse, mutect2, varscan2
- CLDN5 | c.311G>A p.C104Y (on ENST00000618236 / NM_001363066.2; = p.C189Y on NM_003277.4) | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs371581275; called by muse, mutect2, varscan2
- CP | c.2581A>G p.I861V | Missense Mutation (SNP) | VAF 110/234 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.051); catalogued as rs1450174196; called by muse, mutect2, varscan2
- CPN1 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1313931852, COSV64942882; called by muse, mutect2, varscan2
- DDX19B | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 110/360 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.13); catalogued as rs772275413; called by muse, mutect2, varscan2
- DGKB | c.516G>A p.S172= | Splice Region (SNP) | VAF 21/198 reads (11%) | catalogued as COSV51800648; called by muse, mutect2, varscan2
- EFCAB8 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 132/289 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1224074644; called by muse, mutect2, varscan2
- ELF5 | c.669A>T p.R223S (on ENST00000312319 / NM_198381.2; = p.R213S on NM_001422.4) | Missense Mutation (SNP) | VAF 129/283 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.299); catalogued as COSV56629061; called by muse, mutect2, varscan2
- FLG2 | c.4430G>T p.R1477I | Missense Mutation (SNP) | VAF 349/399 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV66169212; called by muse, mutect2, varscan2
- GAL3ST3 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 56/90 reads (62%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.806); catalogued as rs1369967403, COSV61749375; called by muse, mutect2, varscan2
- ISOC1 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 93/141 reads (66%) | SIFT tolerated (0.68); PolyPhen benign (0.051); catalogued as rs1273700428; called by muse, mutect2, varscan2
- KIF1A | c.3806G>A p.R1269Q (on ENST00000320389 / NM_001379639.1; = p.R1261Q on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs753620726, COSV57502608; called by muse, mutect2, varscan2
- KIF1A | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 53/309 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57488038; called by muse, mutect2, varscan2
- KLHL13 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 176/466 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53246790, COSV99452859; called by muse, mutect2, varscan2
- LHPP | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs140370110, COSV100919331; called by muse, mutect2, varscan2
- LRRC7 | c.2375G>A p.R792H (on ENST00000651989 / NM_001370785.2; = p.R759H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.09); catalogued as rs777755924, COSV50409056, COSV50409162; called by muse, mutect2, varscan2
- MAD1L1 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 225/557 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs771673407, COSV56231308; called by muse, mutect2, varscan2
- MBD3L1 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV99978056; called by muse, mutect2
- MXRA5 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 75/240 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV54234479; called by muse, mutect2, varscan2
- MYORG | c.1933G>C p.E645Q | Missense Mutation (SNP) | VAF 114/398 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs1175104111; called by muse, mutect2, varscan2
- NEUROD2 | c.242dup p.E82Rfs*301 | Frame Shift Ins (INS) | VAF 134/434 reads (31%) | catalogued as rs1428384239; called by mutect2, pindel, varscan2
- NUP155 | c.853G>T p.D285Y (on ENST00000231498 / NM_153485.3; = p.D226Y on NM_004298.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759729755; called by mutect2, varscan2
- OPRK1 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs759885797, COSV55569580; called by muse, mutect2, varscan2
- PAX5 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 112/336 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV63908493; called by muse, mutect2, varscan2
- PCDH10 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52088545; called by muse, mutect2, varscan2
- PCDHGA2 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as rs770680401, COSV53893398, COSV53904096; called by muse, mutect2, varscan2
- PPP1R9A | c.2147C>A p.T716N | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs762406102, COSV99198871; called by muse, mutect2
- PTGFR | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 75/75 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as rs1259928177, COSV66115350; called by muse, mutect2, varscan2
- SART3 | c.1855C>T p.R619W (on ENST00000228284; = p.R601W on NM_014706.4) | Missense Mutation (SNP) | VAF 260/566 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs779251233, COSV57207583; called by muse, mutect2, varscan2
- SCN10A | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 178/335 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs748821446, COSV101479595, COSV71860992; called by muse, mutect2, varscan2
- SCN1A | c.2392A>G p.N798D (on ENST00000303395 / NM_001202435.3; = p.N787D on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57664136; called by muse, mutect2, varscan2
- SH3RF3 | c.2486G>A p.R829H | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193350267, COSV58685818; called by muse, mutect2, varscan2
- SOX4 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 72/402 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1179311144, COSV55193493; called by muse, varscan2
- SOX4 | c.1193A>C p.D398A | Missense Mutation (SNP) | VAF 72/406 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1239245615, COSV55193503, COSV55193724; called by muse, varscan2
- STAB2 | c.864C>A p.C288* | Nonsense Mutation (SNP) | VAF 27/165 reads (16%) | catalogued as COSV101185953; called by muse, mutect2, varscan2
- SYNE1 | c.15797C>T p.S5266L (on ENST00000367255 / NM_182961.4; = p.S5195L on NM_033071.3) | Missense Mutation (SNP) | VAF 201/405 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs776756326; called by muse, mutect2, varscan2
- TESMIN | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as rs1350443668; called by muse, mutect2
- TLE4 | c.2059T>A p.L687M | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776801136; called by muse, mutect2, varscan2
- TNS1 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs377519321; called by muse, mutect2, varscan2
- TRPC5 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 153/233 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1346166663, COSV53303238; called by muse, mutect2, varscan2
- TRPV4 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 191/388 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs387907219, CM118758; called by muse, mutect2, varscan2
- TTBK1 | c.3805G>A p.G1269R | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs923481141, COSV52498709; called by muse, mutect2, varscan2
- TTF1 | c.2600A>T p.Y867F | Missense Mutation (SNP) | VAF 211/423 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV100524870; called by muse, mutect2, varscan2
- ZNF518B | c.2648G>A p.S883N | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99045076; called by muse, mutect2, varscan2
- BLM | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 89/129 reads (69%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP128 | c.2960A>T p.D987V | Missense Mutation (SNP) | VAF 57/89 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- DUXB | c.286+1G>C p.X96_splice | Splice Site (SNP) | VAF 92/208 reads (44%) | called by muse, mutect2, varscan2
- ERBB3 | c.2529G>T p.K843N | Missense Mutation (SNP) | VAF 36/453 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); called by muse, mutect2
- FASTK | c.897C>A p.C299* | Nonsense Mutation (SNP) | VAF 91/177 reads (51%) | called by muse, mutect2, varscan2
- FOXE1 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- FZD6 | c.595A>G p.K199E | Missense Mutation (SNP) | VAF 143/322 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- GALNTL6 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2
- GATA6 | c.1529del p.N510Ifs*5 | Frame Shift Del (DEL) | VAF 299/408 reads (73%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.1429C>A p.Q477K | Missense Mutation (SNP) | VAF 17/281 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.009); called by muse, mutect2
- LAMA5 | c.4526G>T p.C1509F | Missense Mutation (SNP) | VAF 61/101 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LGI1 | c.1199T>A p.I400N | Missense Mutation (SNP) | VAF 134/436 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MAGEA8 | c.494T>C p.F165S | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEOX2 | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2
- MFSD12 | c.1340_1342del p.V447del | In Frame Del (DEL) | VAF 21/178 reads (12%) | called by pindel, varscan2
- MICU3 | c.485T>C p.F162S | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- NEK10 | c.163A>T p.N55Y | Missense Mutation (SNP) | VAF 134/308 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- NLRP2 | c.1432T>C p.S478P | Missense Mutation (SNP) | VAF 106/257 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- OGDHL | c.1883_1884del p.G628Afs*51 | Frame Shift Del (DEL) | VAF 16/134 reads (12%) | called by mutect2, varscan2
- PCDHB14 | c.604T>A p.Y202N | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PCDHGC5 | c.211A>T p.N71Y | Missense Mutation (SNP) | VAF 140/205 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PDCD11 | c.4208C>T p.P1403L | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PHACTR1 | c.425G>T p.R142M | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PLCE1 | c.266A>T p.K89I | Missense Mutation (SNP) | VAF 188/489 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RADX | c.2183A>G p.K728R | Missense Mutation (SNP) | VAF 121/217 reads (56%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- RALYL | c.85A>T p.N29Y | Missense Mutation (SNP) | VAF 200/438 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RAVER2 | c.304A>G p.N102D | Missense Mutation (SNP) | VAF 94/106 reads (89%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- RPGRIP1L | c.2276A>T p.N759I | Missense Mutation (SNP) | VAF 161/306 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- SEC23A | c.829-1G>A p.X277_splice | Splice Site (SNP) | VAF 109/179 reads (61%) | called by muse, mutect2, varscan2
- SLC7A13 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 96/230 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SORCS3 | c.2044C>T p.Q682* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | called by muse, mutect2, varscan2
- SPATA31A6 | c.3565G>A p.V1189I | Missense Mutation (SNP) | VAF 80/1470 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.395); called by muse, mutect2
- TCF21 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 176/353 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THEMIS2 | c.1561G>T p.G521W | Missense Mutation (SNP) | VAF 279/279 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TNNT1 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 260/604 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRBV30 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2
- TRPA1 | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 15/262 reads (6%) | called by muse, mutect2
- TSPYL2 | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 166/278 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTC6 | c.62-1G>C p.X21_splice (on ENST00000267368; = p.X1290_splice on NM_001310135.3) | Splice Site (SNP) | VAF 91/144 reads (63%) | called by muse, mutect2, varscan2
- TTN | c.60289A>C p.N20097H (on ENST00000591111; = p.N12673H on NM_003319.4) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC13B | c.1964G>T p.C655F | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- WAS | c.731T>A p.F244Y | Missense Mutation (SNP) | VAF 111/385 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR49 | c.34A>C p.N12H (on ENST00000308378 / NM_001366158.1; = p.N353H on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 134/280 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNT6 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 296/581 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZAN | c.4094T>C p.F1365S | Missense Mutation (SNP) | VAF 180/365 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF257 | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 111/265 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ANAPC1 | c.4212C>T p.L1404= | Silent (SNP) | VAF 44/80 reads (55%) | called by mutect2, varscan2
- FOXE1 | c.813G>A p.P271= | Silent (SNP) | VAF 51/235 reads (22%) | called by muse, mutect2, varscan2
- FZD9 | c.717G>A p.S239= | Silent (SNP) | VAF 89/182 reads (49%) | catalogued as rs781942977, COSV100750932; called by muse, mutect2, varscan2
- GFPT2 | c.471C>T p.F157= | Silent (SNP) | VAF 75/136 reads (55%) | catalogued as rs758739868, COSV53807831; called by muse, mutect2, varscan2
- GPR155 | c.1338G>T p.V446= | Silent (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- HECW1 | c.2295C>T p.G765= | Silent (SNP) | VAF 123/298 reads (41%) | catalogued as rs756411752, COSV67835317; called by muse, mutect2, varscan2
- HTATSF1 | c.12C>T p.T4= | Silent (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2
- ITGB1 | c.45T>C p.V15= | Silent (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- LRRC2 | c.118T>C p.L40= | Silent (SNP) | VAF 70/124 reads (56%) | called by muse, mutect2, varscan2
- LRRC37B | c.1644A>G p.P548= | Silent (SNP) | VAF 88/522 reads (17%) | called by muse, mutect2, varscan2
- MAST1 | c.3924C>T p.A1308= | Silent (SNP) | VAF 125/125 reads (100%) | catalogued as rs751536491; called by muse, mutect2, varscan2
- MECOM | c.1017C>G p.P339= (on ENST00000468789 / NM_001105078.4; = p.P527= on NM_004991.4) | Silent (SNP) | VAF 196/407 reads (48%) | catalogued as rs753495560; called by muse, mutect2, varscan2
- MIIP | c.1107G>A p.P369= | Silent (SNP) | VAF 109/110 reads (99%) | catalogued as rs770778672, COSV52428154; called by muse, mutect2, varscan2
- MKX | c.534C>T p.N178= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs973131909, COSV65391761; called by muse, mutect2, varscan2
- MPDZ | c.3027T>C p.I1009= | Silent (SNP) | VAF 74/275 reads (27%) | called by muse, mutect2, varscan2
- NPAS1 | c.1590G>A p.P530= | Silent (SNP) | VAF 218/424 reads (51%) | catalogued as rs750458086; called by muse, mutect2, varscan2
- OR10AG1 | c.480C>T p.C160= | Silent (SNP) | VAF 72/165 reads (44%) | catalogued as rs754960387, COSV56631269; called by muse, mutect2, varscan2
- PAK3 | c.903A>G p.L301= (on ENST00000262836 / NM_001324328.2; = p.L286= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 129/426 reads (30%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.1947C>T p.H649= | Silent (SNP) | VAF 113/182 reads (62%) | catalogued as COSV54057740; called by muse, mutect2, varscan2
- PDXP | c.273C>T p.C91= | Silent (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- PPIAL4A | c.99G>T p.A33= | Silent (SNP) | VAF 680/759 reads (90%) | called by muse, mutect2, varscan2
- PTPRM | c.2259C>T p.F753= | Silent (SNP) | VAF 140/140 reads (100%) | catalogued as rs749263983, COSV59848593; called by muse, mutect2, varscan2
- SATB1 | c.1314T>C p.A438= | Silent (SNP) | VAF 158/346 reads (46%) | called by muse, mutect2, varscan2
- SHANK1 | c.2190G>T p.V730= | Silent (SNP) | VAF 67/243 reads (28%) | called by muse, mutect2, varscan2
- SND1 | c.2298C>T p.Y766= | Silent (SNP) | VAF 84/190 reads (44%) | catalogued as rs747235161, COSV61235518; called by muse, mutect2, varscan2
- SNED1 | c.2847C>T p.D949= | Silent (SNP) | VAF 114/204 reads (56%) | catalogued as rs368562944; called by muse, mutect2, varscan2
- TCAP | c.333C>A p.I111= | Silent (SNP) | VAF 274/480 reads (57%) | called by muse, mutect2, varscan2
- TFAP2A | c.231C>T p.H77= (on ENST00000482890; = p.H69= on NM_001032280.3) | Silent (SNP) | VAF 35/215 reads (16%) | catalogued as COSV60235006; called by muse, mutect2, varscan2
- TMEM183A | c.333T>A p.T111= | Silent (SNP) | VAF 52/94 reads (55%) | catalogued as COSV65887848; called by muse, mutect2, varscan2
- TUB | c.99G>A p.Q33= | Silent (SNP) | VAF 58/252 reads (23%) | called by muse, mutect2, varscan2
- WDR44 | c.403T>C p.L135= | Silent (SNP) | VAF 109/258 reads (42%) | called by muse, mutect2, varscan2
- CDK5RAP1 | c.1248-82A>T | Intron (SNP) | VAF 55/96 reads (57%) | called by muse, mutect2, varscan2
- COL6A6 | c.4218+828C>A | Intron (SNP) | VAF 9/174 reads (5%) | catalogued as rs1481666378; called by muse, mutect2
- CSHL1 | c.191-17dup | Intron (INS) | VAF 209/598 reads (35%) | catalogued as rs1055509378; called by mutect2, pindel, varscan2
- JCAD | c.*9C>T | 3'UTR (SNP) | VAF 24/282 reads (9%) | catalogued as rs778939984; called by muse, mutect2
- LILRB5 | c.1255+85C>T | Intron (SNP) | VAF 7/69 reads (10%) | catalogued as rs772677955; called by muse, mutect2, varscan2
- MLIP | c.64-37866T>C | Intron (SNP) | VAF 111/248 reads (45%) | called by muse, mutect2, varscan2
- OXR1 | c.-1A>T | 5'UTR (SNP) | VAF 122/293 reads (42%) | called by muse, mutect2, varscan2
- RIMS2 | c.177-44376C>T | Intron (SNP) | VAF 162/318 reads (51%) | catalogued as rs767928685; called by muse, mutect2, varscan2
- SEMA5B | c.3091+13G>A | Intron (SNP) | VAF 116/255 reads (45%) | catalogued as rs367763047; called by muse, mutect2, varscan2
- SYNE1 | c.*9G>T | 3'UTR (SNP) | VAF 70/324 reads (22%) | called by muse, mutect2, varscan2
- UFM1 | c.-11C>T | 5'UTR (SNP) | VAF 327/434 reads (75%) | catalogued as rs1241436854; called by muse, mutect2, varscan2
- ZKSCAN5 | c.*931C>T | 3'UTR (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
